Somatic mutation profile of tumor specimen C3L-00365-01 (aliquot CPT0002410008) from CPTAC case C3L-00365, project CPTAC-3 (Brain — Gliomas). Sex at birth: female; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 59.3 years (21,654 days).
Specimen C3L-00365-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Brain; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c9dfc1ed-a52c-473d-bdcc-e5a608394974.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-00365-31 (Blood Derived Normal), aliquot CPT0004390002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a7fc715a-434d-4c89-8dd0-8fdacd4113c0

The open-access MAF lists 98 somatic variants for this specimen: 63 protein-altering or splice-affecting, 23 silent, 12 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 54, Silent 23, Intron 6, Frame Shift Del 5, Nonsense Mutation 4, RNA 3, 5'Flank 2, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- COL12A1 | c.4300C>T p.R1434* | Nonsense Mutation (SNP) | VAF 28/65 reads (43%) | catalogued as rs1562223444; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TP53 | c.395A>G p.K132R | Missense Mutation (SNP) | VAF 84/107 reads (79%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as rs1057519996, COSV52666637, COSV52701687, COSV52759171; ClinVar: likely pathogenic / uncertain significance; called by muse, mutect2, varscan2
- ABCA13 | c.11324A>G p.N3775S | Missense Mutation (SNP) | VAF 38/135 reads (28%) | SIFT tolerated (0.06); PolyPhen benign (0.221); catalogued as COSV71289820; called by muse, mutect2, varscan2
- ACAN | c.848C>T p.T283M | Missense Mutation (SNP) | VAF 47/96 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs749047801, COSV100716994; called by muse, mutect2, varscan2
- ARSI | c.485G>A p.R162Q | Missense Mutation (SNP) | VAF 110/313 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.833); catalogued as rs1266307168; called by muse, mutect2, varscan2
- CABIN1 | c.4265C>T p.T1422M | Missense Mutation (SNP) | VAF 109/273 reads (40%) | SIFT tolerated (0.25); PolyPhen benign (0.115); catalogued as rs181934556, COSV54077536; called by muse, mutect2, varscan2
- CALHM6 | c.803C>T p.P268L | Missense Mutation (SNP) | VAF 74/154 reads (48%) | SIFT deleterious (0.02); PolyPhen benign (0.244); catalogued as rs199779640, COSV100889473; called by muse, mutect2, varscan2
- CCDC120 | c.1070G>A p.R357H | Missense Mutation (SNP) | VAF 66/173 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs782709167; called by muse, mutect2, varscan2
- CCDC185 | c.994C>T p.R332W | Missense Mutation (SNP) | VAF 94/222 reads (42%) | SIFT deleterious (0); PolyPhen benign (0.131); catalogued as rs778967444; called by muse, mutect2, varscan2
- CDH18 | c.1913G>A p.R638H | Missense Mutation (SNP) | VAF 16/54 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.969); catalogued as rs565236156, COSV56907812, COSV99932062; called by mutect2, varscan2
- CDYL2 | c.1244G>A p.R415Q | Missense Mutation (SNP) | VAF 52/131 reads (40%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.741); catalogued as rs1421470774, COSV101629587; called by muse, mutect2, varscan2
- CFP | c.1202G>A p.R401H | Missense Mutation (SNP) | VAF 164/356 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as rs1223823897, COSV99901707; called by muse, mutect2, varscan2
- CNTNAP3 | c.1802C>T p.P601L | Missense Mutation (SNP) | VAF 47/137 reads (34%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as rs1374325132, COSV52676102, COSV99905386; called by muse, mutect2, varscan2
- CTSG | c.308G>A p.R103Q | Missense Mutation (SNP) | VAF 119/138 reads (86%) | SIFT tolerated (0.5); PolyPhen benign (0); catalogued as rs1475145065, COSV53535207, COSV99361723; called by muse, mutect2, varscan2
- EGFR | c.1994G>A p.G665D | Missense Mutation (SNP) | VAF 4772/5049 reads (95%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.726); catalogued as COSV99286607; called by muse, mutect2, varscan2
- ETS2 | c.436C>T p.R146C | Missense Mutation (SNP) | VAF 122/296 reads (41%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.938); catalogued as rs755635528, COSV62873630; called by muse, mutect2, varscan2
- EVPL | c.3584G>A p.R1195H | Missense Mutation (SNP) | VAF 92/181 reads (51%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as rs762898947; called by muse, mutect2, varscan2
- FBN3 | c.1561G>A p.E521K | Missense Mutation (SNP) | VAF 73/265 reads (28%) | SIFT tolerated (0.17); PolyPhen benign (0.109); catalogued as rs1454120075, COSV54460961; called by muse, mutect2, varscan2
- HNRNPH2 | c.1177G>T p.G393C | Missense Mutation (SNP) | VAF 60/166 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.72); catalogued as COSV100346877; called by muse, mutect2, varscan2
- KCNQ2 | c.2114C>T p.P705L (on ENST00000359125 / NM_172107.4; = p.P677L on NM_004518.6) | Missense Mutation (SNP) | VAF 32/98 reads (33%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.723); catalogued as rs779609892, CD162120, COSV60546961; called by muse, mutect2, varscan2
- KLHL15 | c.674G>T p.C225F | Missense Mutation (SNP) | VAF 48/94 reads (51%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.877); catalogued as COSV60139217; called by muse, mutect2
- KRT23 | c.962G>A p.R321Q | Missense Mutation (SNP) | VAF 114/223 reads (51%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.715); catalogued as rs771092085, COSV99266393; called by muse, mutect2, varscan2
- MC4R | c.533C>T p.T178M | Missense Mutation (SNP) | VAF 156/386 reads (40%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.908); catalogued as rs140040360; called by muse, varscan2
- PDE1A | c.148G>A p.V50I | Missense Mutation (SNP) | VAF 25/90 reads (28%) | SIFT tolerated (0.2); PolyPhen benign (0.003); catalogued as rs747041009, COSV100113615; called by muse, mutect2, varscan2
- POTEC | c.71T>C p.M24T | Missense Mutation (SNP) | VAF 157/374 reads (42%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.822); catalogued as rs564673071; called by muse, mutect2, varscan2
- PPFIA2 | c.541_544del p.F181Sfs*10 | Frame Shift Del (DEL) | VAF 14/96 reads (15%) | catalogued as rs1400362499; called by pindel, varscan2
- RPH3A | c.784C>T p.R262W (on ENST00000389385 / NM_001143854.2; = p.R258W on NM_014954.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 19/63 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.609); catalogued as rs552230104, COSV101231814; called by muse, mutect2, varscan2
- RXRG | c.1279C>T p.R427C | Missense Mutation (SNP) | VAF 128/322 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV63232431; called by muse, mutect2, varscan2
- RYR2 | c.12719C>T p.T4240M | Missense Mutation (SNP) | VAF 162/409 reads (40%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.854); catalogued as COSV63714535; called by muse, mutect2, varscan2
- RYR3 | c.3562G>A p.V1188M | Missense Mutation (SNP) | VAF 70/158 reads (44%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.894); catalogued as rs752683815, COSV101214311; called by muse, mutect2, varscan2
- SAA1 | c.145G>A p.G49S | Missense Mutation (SNP) | VAF 33/131 reads (25%) | SIFT tolerated (0.05); PolyPhen benign (0.271); catalogued as rs765336509, COSV62945864; called by muse, mutect2, varscan2
- SOCS4 | c.1001G>A p.R334K | Missense Mutation (SNP) | VAF 85/115 reads (74%) | SIFT deleterious (0.01); PolyPhen benign (0.074); catalogued as rs1427956800; called by muse, mutect2, varscan2
- TSPAN2 | c.463G>C p.E155Q | Missense Mutation (SNP) | VAF 56/163 reads (34%) | SIFT tolerated (0.54); PolyPhen benign (0.147); catalogued as COSV65690485; called by muse, mutect2, varscan2
- XIRP2 | c.469G>A p.E157K (on ENST00000628543; = p.E332K on NM_152381.6) | Missense Mutation (SNP) | VAF 35/108 reads (32%) | SIFT tolerated (0.17); PolyPhen benign (0); catalogued as rs369173586; called by muse, mutect2, varscan2
- XRRA1 | c.974G>A p.R325Q | Missense Mutation (SNP) | VAF 44/100 reads (44%) | SIFT deleterious (0.02); PolyPhen benign (0.031); catalogued as rs757044769; called by muse, mutect2
- YY2 | c.871G>A p.A291T | Missense Mutation (SNP) | VAF 69/180 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100810856; called by muse, mutect2, varscan2
- ACVR2A | c.1323_1324del p.D443Lfs*13 | Frame Shift Del (DEL) | VAF 45/106 reads (42%) | called by mutect2, pindel, varscan2
- ADAMTS20 | c.2012A>T p.D671V | Missense Mutation (SNP) | VAF 30/82 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.764); called by muse, mutect2, varscan2
- BDNF | c.194A>G p.H65R | Missense Mutation (SNP) | VAF 112/266 reads (42%) | SIFT tolerated (0.11); PolyPhen benign (0.371); called by muse, mutect2, varscan2
- BNC2 | c.308T>A p.L103H | Missense Mutation (SNP) | VAF 85/181 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.65); called by muse, mutect2, varscan2
- CACNA1S | c.4606_4607del p.F1536Hfs*27 | Frame Shift Del (DEL) | VAF 177/554 reads (32%) | called by mutect2, pindel, varscan2
- CHD7 | c.1273G>C p.G425R | Missense Mutation (SNP) | VAF 40/94 reads (43%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.888); called by muse, mutect2, varscan2
- CLEC16A | c.259C>T p.Q87* | Nonsense Mutation (SNP) | VAF 66/203 reads (33%) | called by muse, mutect2, varscan2
- CLEC16A | c.1801C>T p.R601* | Nonsense Mutation (SNP) | VAF 23/69 reads (33%) | called by muse, mutect2, varscan2
- CYSLTR1 | c.159C>A p.H53Q | Missense Mutation (SNP) | VAF 94/186 reads (51%) | SIFT tolerated (0.27); PolyPhen benign (0.339); called by muse, mutect2, varscan2
- GDF3 | c.157A>T p.K53* | Nonsense Mutation (SNP) | VAF 111/263 reads (42%) | called by muse, mutect2, varscan2
- HNRNPH2 | c.93C>A p.F31L | Missense Mutation (SNP) | VAF 53/151 reads (35%) | SIFT tolerated (0.25); PolyPhen benign (0.06); called by muse, mutect2, varscan2
- MUC12 | c.12011del p.P4004Qfs*181 (on ENST00000379442; = p.P3861Qfs*181 on NM_001164462.1) | Frame Shift Del (DEL) | VAF 69/166 reads (42%) | called by mutect2, varscan2
- NOBOX | c.197A>T p.E66V | Missense Mutation (SNP) | VAF 22/580 reads (4%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.007); called by muse, mutect2
- NPHS2 | c.290G>A p.G97D | Missense Mutation (SNP) | VAF 129/323 reads (40%) | SIFT tolerated (0.07); PolyPhen benign (0.019); called by muse, mutect2, varscan2
- OR6V1 | c.451T>G p.F151V | Missense Mutation (SNP) | VAF 79/260 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.91); called by muse, mutect2, varscan2
- PCDHA2 | c.115G>T p.A39S | Missense Mutation (SNP) | VAF 205/431 reads (48%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.105); called by muse, mutect2, varscan2
- RB1 | c.351del p.F117Lfs*8 | Frame Shift Del (DEL) | VAF 55/96 reads (57%) | called by mutect2, pindel, varscan2
- RYK | c.707G>A p.C236Y | Missense Mutation (SNP) | VAF 63/166 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.759); called by muse, mutect2, varscan2
- SESTD1 | c.77G>T p.G26V | Missense Mutation (SNP) | VAF 38/103 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SLC2A4 | c.989G>T p.G330V | Missense Mutation (SNP) | VAF 153/494 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- SULT1C3 | c.142G>C p.D48H | Missense Mutation (SNP) | VAF 19/55 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TRPC4AP | c.1103A>C p.H368P | Missense Mutation (SNP) | VAF 62/229 reads (27%) | SIFT tolerated, low confidence (0.36); PolyPhen benign (0.043); called by muse, mutect2, varscan2
- TRPM6 | c.1610T>A p.L537H | Missense Mutation (SNP) | VAF 125/280 reads (45%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.832); called by muse, mutect2, varscan2
- UGT2B10 | c.1062G>T p.K354N | Missense Mutation (SNP) | VAF 51/117 reads (44%) | SIFT tolerated (0.08); PolyPhen benign (0.068); called by muse, mutect2, varscan2
- ZNF143 | c.1369C>T p.P457S | Missense Mutation (SNP) | VAF 8/163 reads (5%) | SIFT tolerated (0.11); PolyPhen benign (0.015); called by muse, mutect2
- ZNF717 | c.1837C>T p.H613Y | Missense Mutation (SNP) | VAF 44/290 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); called by muse, mutect2
- ZNF808 | c.1845A>T p.R615S | Missense Mutation (SNP) | VAF 61/177 reads (34%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.813); called by muse, mutect2, varscan2
- AMER3 | c.528G>A p.S176= | Silent (SNP) | VAF 65/121 reads (54%) | catalogued as rs776935592, COSV58467357, COSV58469465; called by muse, mutect2, varscan2
- BEAN1 | c.297C>T p.D99= | Silent (SNP) | VAF 25/66 reads (38%) | catalogued as rs947076270; called by muse, mutect2
- CACNA1B | c.5403G>A p.T1801= | Silent (SNP) | VAF 38/88 reads (43%) | catalogued as rs200789295; called by muse, mutect2, varscan2
- DSG3 | c.1941T>C p.S647= | Silent (SNP) | VAF 110/224 reads (49%) | called by muse, mutect2, varscan2
- FAM155B | c.639C>G p.R213= | Silent (SNP) | VAF 109/270 reads (40%) | called by muse, mutect2, varscan2
- FCGBP | c.5784C>T p.A1928= | Silent (SNP) | VAF 30/494 reads (6%) | catalogued as rs1292505819; called by muse, mutect2
- GABRA5 | c.1374C>T p.A458= | Silent (SNP) | VAF 17/71 reads (24%) | catalogued as rs778204274, COSV59481809; called by muse, mutect2, varscan2
- GIMAP5 | c.114C>T p.C38= | Silent (SNP) | VAF 77/235 reads (33%) | catalogued as rs149695569, COSV57529925; called by muse, mutect2, varscan2
- GOLGA6L2 | c.1347G>A p.E449= | Silent (SNP) | VAF 80/203 reads (39%) | called by muse, mutect2, varscan2
- MAPK8IP1 | c.1329C>T p.L443= | Silent (SNP) | VAF 59/120 reads (49%) | called by muse, mutect2, varscan2
- MGA | c.1279C>T p.L427= | Silent (SNP) | VAF 69/149 reads (46%) | catalogued as COSV54954725; called by muse, mutect2, varscan2
- NECTIN4 | c.225C>T p.G75= | Silent (SNP) | VAF 108/268 reads (40%) | catalogued as rs937433184, COSV63513711; called by muse, mutect2, varscan2
- NELL1 | c.1158C>T p.C386= | Silent (SNP) | VAF 38/133 reads (29%) | called by muse, mutect2, varscan2
- NLRP8 | c.699C>T p.Y233= | Silent (SNP) | VAF 86/324 reads (27%) | catalogued as rs377108884; called by muse, mutect2, varscan2
- OR2A7 | c.78C>T p.L26= | Silent (SNP) | VAF 69/613 reads (11%) | called by muse, mutect2, varscan2
- OR4K13 | c.327G>T p.G109= | Silent (SNP) | VAF 72/95 reads (76%) | called by muse, mutect2, varscan2
- PCDH19 | c.1668C>T p.V556= | Silent (SNP) | VAF 181/436 reads (42%) | catalogued as rs1468984936; called by muse, mutect2, varscan2
- PCLO | c.4143T>C p.I1381= | Silent (SNP) | VAF 51/193 reads (26%) | called by muse, mutect2, varscan2
- PER1 | c.1929C>T p.L643= | Silent (SNP) | VAF 20/54 reads (37%) | called by muse, mutect2, varscan2
- PRODH2 | c.63C>T p.N21= | Silent (SNP) | VAF 24/113 reads (21%) | catalogued as rs924130595; called by muse, mutect2, varscan2
- TGM6 | c.1608C>T p.I536= | Silent (SNP) | VAF 64/240 reads (27%) | catalogued as COSV99171812; called by muse, mutect2, varscan2
- TRIM64C | c.999G>A p.A333= | Silent (SNP) | VAF 74/189 reads (39%) | catalogued as rs202107255, COSV73267404; called by muse, mutect2, varscan2
- UTS2R | c.381C>T p.F127= | Silent (SNP) | VAF 104/241 reads (43%) | catalogued as rs769997568; called by muse, mutect2, varscan2
- ADAMTSL3 | c.802+2680A>T | Intron (SNP) | VAF 8/25 reads (32%) | called by muse, mutect2, varscan2
- CPE | c.307+6803T>C | Intron (SNP) | VAF 36/77 reads (47%) | called by muse, mutect2, varscan2
- DNMBP | c.2261-20944T>C | Intron (SNP) | VAF 38/53 reads (72%) | called by muse, mutect2, varscan2
- ERVV-1 | chr19:53009558 G>A | 5'Flank (SNP) | VAF 51/199 reads (26%) | catalogued as rs952698410; called by muse, mutect2, varscan2
- ETFA | c.882+2477C>T | Intron (SNP) | VAF 5/9 reads (56%) | catalogued as rs1279542809; called by muse, mutect2, varscan2
- MIR519E | n.10G>T | RNA (SNP) | VAF 31/111 reads (28%) | called by muse, mutect2, varscan2
- MIR9-1 | n.20T>C | RNA (SNP) | VAF 37/116 reads (32%) | called by muse, mutect2, varscan2
- RBM3 | chrX:48574618 C>T | 5'Flank (SNP) | VAF 80/176 reads (45%) | called by muse, mutect2, varscan2
- SHANK2 | c.1108-56165C>T | Intron (SNP) | VAF 14/24 reads (58%) | catalogued as rs782447602; called by muse, mutect2, varscan2
- TRPA1 | c.-48C>T | 5'UTR (SNP) | VAF 66/153 reads (43%) | catalogued as COSV100084252; called by muse, mutect2, varscan2
- URB1 | c.664+1224C>T | Intron (SNP) | VAF 16/220 reads (7%) | catalogued as rs779180238; called by muse, mutect2
- WASH8P | n.824T>C | RNA (SNP) | VAF 91/510 reads (18%) | called by mutect2, varscan2
